Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A4MT, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A4MT-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Addendum Present

Date of Procedure:
Date Received:

Race: CAUCASIAN
DOB/Sex: / F

FINAL DIAGNOSIS

A, B. SUPERFICIAL AND DEEPER ENHANCING TUMOR, BIOPSIES:
-- INFILTRATING OLIGODENDROGLIOMA.

C-E. LEFT TEMPORAL NEOPLASM, REMOVAL:
-- OLIGODENDROGLIOMA (WHO GRADE II).

Note: An addendum will be issued pending analyses for chromosomes 1p and 19q deletions.

Electronically Signed Out By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

- A. SUPERFICIAL TUMOR: microscopic: Astrocytoma, grade 2.
- B. DEEPER ENHANCING TUMOR: microscopic: Astrocytoma, grade 2.
- C. microscopic: Anaplastic Astrocytoma.

100-0-3
Oligodendroglioma, NOS 9450/3
Site: brain, temporal lobe C71.2
hw
10/4/12

Addendum/Procedures:

Addendum

Date Ordered:
Date Complete:
Date Reported:

Status: Signed Out

Addendum Diagnosis

Florescence in situ hybridization, performed at the [REDACTED], demonstrates **preservation of chromosome 1p** and **loss of chromosome 19q**.

Electronically Signed Out By

Clinical History:

Left temporal mass

Specimens Submitted As:

- A: SUPERFICIAL TUMOR
- B: DEEPER ENHANCING TUMOR
- C: HEMORRHAGIC TUMOR
- D: LEFT TEMPORAL NEOPLASM
- E: CUSA CONTENTS

Gross Description:

A: Received fresh for intraoperative consultation, labeled with the patient's name and hospital number, is a 1x 0.5 x 0.5 cm tan white piece of soft tissue. The specimen is submitted entirely in 2 cassettes.

For Malignancy History		

hw
10/4/12

[page 2 of 2]
B: Received fresh for intraoperative consultation, labeled with the patient's name and hospital number, are three, 1.2 x 0.5 x 0.5 cm, tan red to white pieces of soft tissue. The specimen is submitted entirely in 2 cassettes.

C: Received fresh for intraoperative consultation, labeled with the patient's name and hospital number, are multiple, 1.5 x 1 x 0.3 cm, tan red to white pieces of soft tissue. The specimen is submitted entirely in 1 cassettes.

D: Received fresh, labeled with the patient's name and number, and "left temporal neoplasm", are multiple irregular, opaque white to pink-tan, soft, cerebriform tissue fragments measuring in aggregate 5.0 x 5.0 x 1.2 cm. A portion is submitted to [REDACTED]. The remaining tissue is submitted entirely in 6 cassettes.

E: Received fresh, post in formalin, labeled with the patient's name and number, and "Cusa contents", is a sock containing multiple irregular, opaque white to tan brown, soft tissue fragments measuring in aggregate 3.8 x 3.8 x 1.2 cm. Submitted in toto in 3 cassettes.

Summary of cassettes

A1 FS

A2 remainder of specimen

B1 FS

B2 remainder of specimen

Source: NCI Genomic Data Commons file 4d4c6c44-0a32-4786-85c1-5fcfb7869513 (TCGA-FG-A4MT.5FBDAD09-6FC1-41FF-9361-0184C122246B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).